Somatic mutation profile of tumor specimen 0DUQYY from CCDI case PBCLUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,699 days).
Specimen 0DUQYY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c6f393e-5e88-49c3-9f4a-1ca72c1aa73f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUR06 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4a6a4f9-234d-494f-87e2-708a3ad3220c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BUD23 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 40/721 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.223); catalogued as rs1554613171; called by muse, mutect2
- MACF1 | c.2431C>T p.R811* | Nonsense Mutation (SNP) | VAF 53/797 reads (7%) | catalogued as COSV100485809; called by muse, mutect2
- TTC4 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 53/670 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1195039315, COSV64885053; called by muse, mutect2
- KRT12 | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MAGED1 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 80/722 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC4 | c.2197T>A p.S733T | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2
- RBM27 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 271/690 reads (39%) | called by muse, mutect2, varscan2
- SLC25A32 | c.75C>A p.N25K | Missense Mutation (SNP) | VAF 131/727 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ABCB8 | c.978+19A>T | Intron (SNP) | VAF 16/563 reads (3%) | called by muse, mutect2
- BEST3 | c.248-66A>C | Intron (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- DNAH14 | c.2938+1885G>T | Intron (SNP) | VAF 52/688 reads (8%) | called by muse, mutect2
